Somatic mutation profile of tumor specimen TCGA-EB-A550-01A (aliquot TCGA-EB-A550-01A-61D-A27K-08) from TCGA case TCGA-EB-A550, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 75.4 years (27,556 days).
Specimen TCGA-EB-A550-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7567b67f-cdc4-41a4-a7ac-ec53083d20f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A550-10A (Blood Derived Normal), aliquot TCGA-EB-A550-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12dcf229-d871-46eb-9dd1-597e0d00b7cf

The open-access MAF lists 176 somatic variants for this specimen: 128 protein-altering or splice-affecting, 44 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 44, Nonsense Mutation 6, Splice Site 6, Frame Shift Del 3, 3'Flank 2, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2ML1 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs780281065, COSV55287724; called by muse, mutect2, varscan2
- ADAM18 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV55844347; called by muse, mutect2, varscan2
- ADRA1A | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs748492860, COSV52366575, COSV99372034; called by muse, mutect2, varscan2
- ALLC | c.700T>G p.W234G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378366; called by muse, mutect2, varscan2
- ALMS1 | c.10891C>T p.R3631C | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762251180, COSV52501896; called by muse, mutect2, varscan2
- AMMECR1L | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.345); catalogued as COSV99761594; called by muse, mutect2
- APOOL | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs763022623, COSV100261152; called by muse, varscan2
- ARHGEF10L | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394050; called by muse, mutect2, varscan2
- ATP5PB | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100867657; called by muse, mutect2, varscan2
- BBS2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99802929; called by muse, mutect2, varscan2
- BMP15 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53140771, COSV99399572; called by muse, mutect2, varscan2
- C8A | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs773423532, COSV63486032; called by muse, mutect2, varscan2
- CASR | c.2825G>A p.G942E (on ENST00000490131; = p.G1019E on NM_000388.4) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99948635, COSV99949571; called by muse, mutect2, varscan2
- CCDC116 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99489531; called by muse, mutect2, varscan2
- CCDC14 | c.2489C>T p.T830I (on ENST00000488653; = p.T782I on NM_022757.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100113501; called by muse, mutect2, varscan2
- CD40 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100953882; called by muse, mutect2, varscan2
- CDH12 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765231841, COSV66389349; called by muse, mutect2, varscan2
- CIB2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV51948520; called by muse, mutect2, varscan2
- CMYA5 | c.2332G>A p.V778M | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as rs768209540, COSV101484445; called by muse, mutect2, varscan2
- CNTNAP4 | c.644T>A p.M215K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV100273681; called by muse, mutect2, varscan2
- COL21A1 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99780563; called by muse, mutect2, varscan2
- CPAMD8 | c.1237-1G>A p.X413_splice (on ENST00000651564; = p.X366_splice on NM_015692.5) | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99359898; called by muse, mutect2
- CPT1B | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV56419555; called by muse, mutect2, varscan2
- CSTA | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99138696; called by muse, mutect2, varscan2
- CTC1 | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100236886; called by muse, mutect2, varscan2
- CUZD1 | c.101T>G p.V34G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100159040; called by muse, mutect2, varscan2
- CUZD1 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100159042; called by muse, mutect2, varscan2
- CYP17A1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100882154; called by muse, mutect2
- DCN | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99272882; called by muse, mutect2, varscan2
- DDIT3 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV56257411; called by muse, mutect2, varscan2
- DGKK | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs376854796, COSV65706953; called by muse, mutect2, varscan2
- DHRSX | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1197660127, COSV100586148; called by muse, mutect2, varscan2
- DLGAP2 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs982240696, COSV101422961; called by muse, mutect2, varscan2
- DLK1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746359450, COSV100375505; called by muse, mutect2, varscan2
- DNAH5 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99455298; called by muse, mutect2, varscan2
- DSE | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs762084403, COSV59062453; called by muse, mutect2, varscan2
- DTD1 | c.606C>G p.D202E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV101080124; called by muse, mutect2, varscan2
- ERBB4 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV61482964; called by muse, mutect2, varscan2
- FAT4 | c.13880C>T p.A4627V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100630504; called by muse, mutect2, varscan2
- GATA2 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777230453, COSV100351604; called by muse, mutect2, varscan2
- GRM8 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833155; called by muse, mutect2, varscan2
- HAL | c.336+1G>A p.X112_splice | Splice Site (SNP) | VAF 34/164 reads (21%) | catalogued as COSV99701703; called by muse, mutect2, varscan2
- HAPLN4 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV52268940, COSV99364086; called by muse, mutect2, varscan2
- HSPA1L | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.698); catalogued as rs142416335; called by muse, mutect2, varscan2
- INPP5D | c.1875G>T p.R625S (on ENST00000445964 / NM_001017915.3; = p.R624S on NM_005541.5) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100857003; called by muse, mutect2, varscan2
- INVS | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99318395; called by muse, mutect2, varscan2
- ITGA7 | c.2672C>T p.S891F (on ENST00000555728; = p.S847F on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.149); catalogued as COSV99165216; called by muse, mutect2, varscan2
- KCTD16 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72577135; called by muse, mutect2, varscan2
- KIAA0753 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as rs1208145718, COSV100810726, COSV63816724; called by muse, mutect2, varscan2
- KIF26A | c.2596G>A p.G866R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs779918856, COSV59466087, COSV59470519; called by muse, mutect2, varscan2
- KIF26A | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV100181653; called by muse, mutect2, varscan2
- KLF6 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV51495626; called by muse, mutect2, varscan2
- KLF6 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99435349; called by muse, mutect2, varscan2
- KLK12 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99142120; called by muse, mutect2, varscan2
- KLK5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as rs748294116, COSV60449437; called by muse, mutect2, varscan2
- KRT78 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100398580; called by muse, mutect2, varscan2
- LIPI | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754059; called by muse, mutect2, varscan2
- LPA | c.4189C>T p.R1397* | Nonsense Mutation (SNP) | VAF 48/271 reads (18%) | catalogued as rs200154828, COSV60299838; called by muse, mutect2, varscan2
- LRATD1 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as COSV99707328; called by muse, mutect2, varscan2
- LRRC10 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as rs765309757, COSV64060130; called by muse, mutect2, varscan2
- LRRC37A3 | c.3502C>T p.L1168F | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1268425888, COSV100141567; called by muse, mutect2, varscan2
- LUM | c.863-2A>G p.X288_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99899221; called by muse, mutect2, varscan2
- MACC1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs749712233, COSV100256366; called by muse, mutect2, varscan2
- MAGEC1 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV99596770; called by muse, mutect2, varscan2
- MAGEC2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99910016; called by muse, mutect2, varscan2
- MAGIX | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100891945; called by muse, mutect2
- MUC16 | c.28562C>T p.S9521F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV101202074; called by muse, mutect2, varscan2
- MUC4 | c.2044G>T p.V682F | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as COSV100642580; called by muse, mutect2, varscan2
- MXRA5 | c.6136C>T p.P2046S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99479715; called by muse, mutect2, varscan2
- MXRA5 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54249955; called by muse, mutect2, varscan2
- NDST3 | c.1070-1G>A p.X357_splice | Splice Site (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99632187; called by muse, mutect2, varscan2
- NPAS4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100215335; called by muse, mutect2, varscan2
- NWD1 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.444); catalogued as COSV60340643; called by muse, mutect2, varscan2
- OR10G9 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201958456, COSV100901795; called by muse, mutect2, varscan2
- OR13C8 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV58611373; called by muse, mutect2, varscan2
- OR1B1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100506567; called by muse, mutect2, varscan2
- OR1N1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs773689902, COSV100509863; called by muse, mutect2, varscan2
- OR2G2 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs889173389, COSV100190051; called by muse, mutect2, varscan2
- OR4K15 | c.370C>T p.Q124* (on ENST00000305051; = p.Q100* on NM_001005486.1) | Nonsense Mutation (SNP) | VAF 28/207 reads (14%) | catalogued as COSV100521185; called by muse, mutect2, varscan2
- OR4M1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60063023, COSV60063140; called by muse, mutect2, varscan2
- OR52E2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384961; called by muse, mutect2, varscan2
- OR6C74 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.056); catalogued as rs777439706, COSV59605795; called by muse, mutect2, varscan2
- OSBPL6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.98); catalogued as COSV99507680; called by muse, mutect2, varscan2
- PCDH11X | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 109/409 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53442058; called by muse, mutect2, varscan2
- PDZD2 | c.3950C>G p.T1317S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99227124; called by muse, mutect2, varscan2
- PIK3C2G | c.3232G>A p.D1078N (on ENST00000676171; = p.D1037N on NM_004570.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854370; called by muse, mutect2
- PIK3R4 | c.2998A>G p.R1000G | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.268); catalogued as COSV100768638, COSV63243431; called by muse, mutect2, varscan2
- PLA2G1B | c.126G>T p.L42F | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100387582; called by muse, mutect2, varscan2
- PNKP | c.637-1G>T p.X213_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV55587660, COSV99682109; called by muse, mutect2, varscan2
- PPFIBP2 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1397296211, COSV100207132, COSV55079802; called by muse, mutect2, varscan2
- PRKX | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as COSV99468765; called by muse, mutect2, varscan2
- PRPS1L1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV101552953, COSV101552962; called by muse, mutect2, varscan2
- PRSS35 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100864167; called by muse, mutect2, varscan2
- PRXL2A | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100939846; called by muse, mutect2, varscan2
- PTPN3 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV99356332; called by muse, mutect2, varscan2
- RBBP6 | c.2035C>T p.R679C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs757145338, COSV60503738; called by muse, mutect2, varscan2
- REPS2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV100381760; called by muse, mutect2, varscan2
- RGS7 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100471595; called by muse, mutect2, varscan2
- RPS6KB2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV100412406; called by muse, mutect2, varscan2
- SALL3 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs763450217, COSV101610075, COSV73305734; called by muse, mutect2, varscan2
- SERPINB11 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV66958055; called by muse, mutect2
- SGK3 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100616915; called by muse, mutect2, varscan2
- SGMS1 | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100693822; called by muse, mutect2, varscan2
- SHROOM4 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs371697426, COSV56784797; called by muse, mutect2, varscan2
- SIRPB1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183947378, COSV99498648; called by muse, mutect2, varscan2
- SLC46A1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368657591; called by muse, mutect2, varscan2
- SMOX | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs765487941, COSV53864968; called by muse, mutect2, varscan2
- SZT2 | c.5720C>T p.S1907L (on ENST00000634258 / NM_001365999.1; = p.S1850L on NM_015284.4) | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs773776840, COSV100987715; called by muse, mutect2, varscan2
- TAF1L | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998290032, COSV54260013; called by muse, mutect2, varscan2
- TCEAL5 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.997); catalogued as COSV101013200; called by muse, mutect2, varscan2
- THEMIS | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs758582495, COSV64073180, COSV64075084; called by muse, mutect2, varscan2
- TSKS | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.915); catalogued as COSV55873311; called by muse, mutect2
- USP34 | c.9541C>T p.H3181Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101081869; called by muse, mutect2, varscan2
- VSX1 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100942235; called by muse, mutect2, varscan2
- WDR59 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV100049796; called by muse, mutect2, varscan2
- ZBTB7A | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs866867944, COSV100476018; called by muse, mutect2, varscan2
- ZDBF2 | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100985666, COSV65630242; called by muse, mutect2
- ZNF607 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100777977; called by muse, mutect2, varscan2
- ZNF620 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as COSV100094215; called by muse, mutect2, varscan2
- ZNF766 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100765501; called by muse, mutect2, varscan2
- ZSWIM3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV54849913; called by muse, mutect2, varscan2
- H2AC6 | c.100dup p.L34Pfs*4 | Frame Shift Ins (INS) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KCTD13 | c.615del p.F206Sfs*59 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- MYO16 | c.943del p.M315* | Frame Shift Del (DEL) | VAF 32/141 reads (23%) | called by mutect2, pindel, varscan2
- NCOA3 | c.1835del p.P612Lfs*26 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- TMEM209 | c.1457_1459+26del p.X486_splice | Splice Site (DEL) | VAF 48/200 reads (24%) | called by mutect2, pindel
- ACVRL1 | c.135C>T p.T45= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101188222; called by muse, mutect2, varscan2
- AF196969.1 | c.249C>T p.F83= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs782366560, COSV99339462; called by muse, mutect2, varscan2
- ANKRD45 | c.576C>T p.L192= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs142022432; called by muse, mutect2, varscan2
- ASTN1 | c.276C>T p.F92= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs762270867, COSV56072638; called by muse, mutect2, varscan2
- ATP2B2 | c.1857C>T p.I619= (on ENST00000352432; = p.I585= on NM_001683.5) | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs373144988; called by muse, mutect2, varscan2
- ATP2C2 | c.2205C>T p.F735= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as COSV99298741; called by muse, mutect2, varscan2
- CSF2RB | c.2490C>T p.P830= | Silent (SNP) | VAF 61/320 reads (19%) | catalogued as rs143285765; called by muse, mutect2, varscan2
- CSMD2 | c.6438C>T p.T2146= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV53903298; called by muse, mutect2, varscan2
- ELN | c.246C>T p.F82= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV52709470; called by muse, mutect2, varscan2
- ELOVL7 | c.414G>A p.K138= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101415656; called by muse, mutect2, varscan2
- EPHB1 | c.534G>A p.Q178= | Silent (SNP) | VAF 61/344 reads (18%) | catalogued as COSV67669188; called by muse, mutect2, varscan2
- EPS8L3 | c.1665G>A p.T555= (on ENST00000361965 / NM_133181.4; = p.T525= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs763352581, COSV100719768; called by muse, mutect2, varscan2
- FAM135B | c.4203A>T p.G1401= | Silent (SNP) | VAF 74/284 reads (26%) | catalogued as COSV52720408, COSV99428453; called by muse, mutect2, varscan2
- FANCL | c.528C>T p.S176= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99288058; called by muse, mutect2, varscan2
- GEMIN5 | c.1443A>C p.P481= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99594414; called by muse, mutect2, varscan2
- GPKOW | c.489C>T p.P163= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs138799430, COSV99332839; called by muse, mutect2, varscan2
- GPR162 | c.1452G>A p.E484= (on ENST00000311268 / NM_019858.2; = p.E200= on NM_014449.2) | Silent (SNP) | VAF 41/235 reads (17%) | catalogued as COSV99301796; called by muse, mutect2, varscan2
- GRIK1 | c.2253G>A p.L751= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1166965874, COSV100518171; called by muse, mutect2, varscan2
- IK | c.393C>T p.P131= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV101341832; called by muse, mutect2, varscan2
- KIAA1755 | c.375C>T p.S125= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV99642825; called by muse, mutect2, varscan2
- KRT77 | c.1389C>T p.I463= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs776967209, COSV100527316; called by muse, mutect2, varscan2
- LILRA1 | c.504G>T p.L168= | Silent (SNP) | VAF 55/326 reads (17%) | catalogued as COSV99252295; called by muse, mutect2, varscan2
- LRP10 | c.597C>T p.F199= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs1283945007, COSV100612534, COSV62078824; called by muse, mutect2, varscan2
- MUC4 | c.216T>C p.A72= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV62134977; called by muse, mutect2, varscan2
- NOTCH3 | c.5541C>T p.A1847= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1390061538, COSV99659199; called by muse, mutect2, varscan2
- OR5AR1 | c.432C>T p.L144= | Silent (SNP) | VAF 59/242 reads (24%) | catalogued as rs1401103976, COSV57254356; called by muse, mutect2, varscan2
- PDE11A | c.2349G>A p.R783= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99615651; called by muse, mutect2, varscan2
- POLQ | c.6219C>T p.F2073= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51758304; called by muse, mutect2, varscan2
- RBM11 | c.507C>T p.S169= | Silent (SNP) | VAF 66/306 reads (22%) | catalogued as rs183317101, COSV101271254; called by muse, varscan2
- RDH16 | c.24C>T p.F8= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as rs771014684, COSV100660186; called by muse, mutect2, varscan2
- SAFB2 | c.2520C>T p.P840= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53042782; called by muse, mutect2
- SLC10A2 | c.219C>T p.L73= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as COSV99807656; called by muse, mutect2, varscan2
- SLC26A9 | c.537C>T p.L179= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs769181005, COSV100536924; called by muse, mutect2, varscan2
- SLC2A12 | c.1308C>T p.S436= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as COSV99259761, COSV99260708; called by muse, mutect2, varscan2
- SMS | c.810T>C p.F270= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV101048319; called by muse, mutect2, varscan2
- SNRNP27 | c.333C>T p.S111= | Silent (SNP) | VAF 59/197 reads (30%) | catalogued as COSV99732289; called by muse, mutect2, varscan2
- SRRM4 | c.1146G>A p.R382= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs749346406, COSV57413214; called by muse, mutect2, varscan2
- SYTL5 | c.660G>A p.R220= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs866482454, COSV99937746; called by muse, mutect2, varscan2
- TIMM17B | c.441C>T p.F147= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99504626; called by muse, mutect2, varscan2
- TNIP3 | c.711C>T p.S237= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV99284914; called by muse, mutect2, varscan2
- UGT1A7 | c.612G>A p.K204= | Silent (SNP) | VAF 60/291 reads (21%) | catalogued as rs147392032; called by muse, mutect2, varscan2
- UNC93A | c.216C>T p.I72= | Silent (SNP) | VAF 98/398 reads (25%) | catalogued as COSV100023739; called by muse, mutect2, varscan2
- WFDC5 | c.78G>A p.K26= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1318892532, COSV100332224; called by muse, mutect2, varscan2
- XYLT1 | c.2181C>T p.I727= | Silent (SNP) | VAF 68/285 reads (24%) | catalogued as rs112238716; called by muse, mutect2, varscan2
- AGAP2 | chr12:57741951 G>A | 5'Flank (SNP) | VAF 30/159 reads (19%) | catalogued as COSV99224495; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851149 C>T | 3'Flank (SNP) | VAF 83/389 reads (21%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640574 G>A | 3'Flank (SNP) | VAF 25/84 reads (30%) | catalogued as rs776752330, COSV51703847; called by muse, mutect2, varscan2
- TTN | c.10360+3833C>T | Intron (SNP) | VAF 27/109 reads (25%) | catalogued as rs1408810089, COSV100634322; called by muse, mutect2, varscan2
